Somatic mutation profile of tumor specimen TCGA-D6-6826-01A (aliquot TCGA-D6-6826-01A-11D-1912-08) from TCGA case TCGA-D6-6826, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.9 years (23,722 days).
Specimen TCGA-D6-6826-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b189ef79-9843-499d-87ab-6a379ae10d52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-6826-10A (Blood Derived Normal), aliquot TCGA-D6-6826-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05925d2f-b161-4041-892d-7d95bd7a18e8

The open-access MAF lists 110 somatic variants for this specimen: 82 protein-altering or splice-affecting, 21 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 21, Nonsense Mutation 6, RNA 3, Splice Site 2, Intron 2, Frame Shift Ins 2, Frame Shift Del 1, Nonstop Mutation 1, 5'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA1 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs1085308014, COSV100796784; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANTXR1 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 21/189 reads (11%) | catalogued as rs397514700, CM133664, COSV58013730; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.518T>G p.V173G | Missense Mutation (SNP) | VAF 35/73 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519747, COSV52679619, COSV52753659, COSV52782945; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs753476988, COSV99791339; called by muse, varscan2
- ABCC5 | c.1376A>G p.E459G | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99657326; called by muse, mutect2, varscan2
- ADGRG5 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs149449822; called by muse, mutect2, varscan2
- ALOX12B | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs1411601149, COSV59871577; called by mutect2, varscan2
- ALPK1 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99452821; called by mutect2, varscan2
- ARHGAP5 | c.3655G>A p.D1219N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.131); catalogued as COSV100565620; called by muse, mutect2, varscan2
- ASAP1 | c.2168A>T p.D723V | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV100727655; called by muse, mutect2, varscan2
- ATP2A2 | c.2189C>G p.S730C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100428542, COSV100428825; called by muse, mutect2, varscan2
- BHMT2 | c.925A>G p.R309G | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs1012849436, COSV99670250; called by muse, mutect2, varscan2
- BTN1A1 | c.1440G>C p.E480D | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99764501; called by muse, mutect2, varscan2
- CIP2A | c.2422A>T p.T808S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99843074; called by muse, mutect2, varscan2
- CPVL | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.253); catalogued as COSV99606272; called by muse, mutect2, varscan2
- CREB3L4 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs146463170, COSV99665796; called by muse, mutect2, varscan2
- CRISP3 | c.308A>G p.N103S (on ENST00000371159 / NM_001368123.1; = p.N85S on NM_006061.4) | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as COSV99539145; called by muse, mutect2, varscan2
- DDR1 | c.2525C>T p.A842V (on ENST00000324771; = p.A805V on NM_001954.4) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100241916; called by muse, mutect2, varscan2
- DNAH2 | c.7842C>G p.F2614L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101209523; called by muse, mutect2, varscan2
- DPYD | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1290815802, COSV100929258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSEL | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.304); catalogued as COSV100025952; called by muse, mutect2, varscan2
- DYRK4 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs774187466, COSV50537774; called by muse, mutect2, varscan2
- E4F1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs751937000, COSV100065985; called by muse, mutect2, varscan2
- ECPAS | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745639002, COSV99398987; called by muse, mutect2, varscan2
- FAM135B | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99426283; called by muse, mutect2
- FARP1 | c.2253C>A p.D751E | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.462); catalogued as COSV100131751; called by muse, mutect2, varscan2
- FCRL2 | c.1160C>G p.S387* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV100829974; called by muse, mutect2, varscan2
- FLG | c.4925G>C p.S1642T | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.258); catalogued as COSV100911938; called by muse, mutect2, varscan2
- FMR1NB | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.546); catalogued as COSV100975588, COSV65073266; called by muse, mutect2, varscan2
- GAS2L1 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53330840, COSV99329646; called by muse, mutect2, varscan2
- GBF1 | c.2962C>G p.L988V (on ENST00000369983 / NM_001377137.1; = p.L987V on NM_004193.3) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100890618, COSV64142974; called by muse, mutect2, varscan2
- GNAS | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.251); catalogued as COSV55677367, COSV99670773; called by muse, mutect2, varscan2
- GP5 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100540987; called by muse, mutect2, varscan2
- GPX2 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs1236515086, COSV100767475; called by muse, mutect2, varscan2
- HNF4G | c.1142G>T p.G381V (on ENST00000354370 / NM_001330561.2; = p.G428V on NM_004133.5) | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.103); catalogued as COSV100584867, COSV62971287; called by muse, mutect2, varscan2
- IGKC | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs748013609; called by muse, mutect2, varscan2
- KLHDC7A | c.1987G>A p.G663R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV101272835; called by muse, mutect2, varscan2
- LIX1L | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as rs1045241099, COSV63417102; called by muse, mutect2, varscan2
- LRP2 | c.8255G>A p.R2752Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs750566206, COSV55539276, COSV99789744; called by muse, mutect2, varscan2
- LRRC7 | c.2108-1G>T p.X703_splice (on ENST00000651989 / NM_001370785.2; = p.X670_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99228790; called by muse, mutect2, varscan2
- MAEL | c.1277G>C p.G426A | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.206); catalogued as COSV100901928; called by muse, mutect2
- MAGEA11 | c.96+2T>A p.X32_splice | Splice Site (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100290632; called by muse, mutect2, varscan2
- MS4A7 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1326492620, COSV55729369, COSV55729706; called by muse, mutect2, varscan2
- NEXN | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99630548; called by muse, mutect2, varscan2
- OCEL1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99285799; called by muse, varscan2
- OR1S2 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs138124206, COSV56919939; called by muse, mutect2, varscan2
- OR2T6 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs371476686, COSV63215950; called by muse, mutect2, varscan2
- PAM | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755661759, COSV99173694; called by muse, mutect2, varscan2
- PCDHGC5 | c.2361C>A p.F787L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99341691; called by muse, mutect2, varscan2
- PDP1 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.221); catalogued as rs201452113, COSV99892760; called by muse, mutect2
- PRAMEF4 | c.337A>T p.N113Y | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99340061; called by muse, mutect2, varscan2
- PTGES3 | c.482A>C p.*161Sext*9 | Nonstop Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100009799; called by muse, mutect2, varscan2
- RASA3 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766568683, COSV100481049; called by muse, mutect2, varscan2
- RIN3 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs767768159, COSV99379756; called by muse, mutect2, varscan2
- RNF216 | c.757G>C p.E253Q (on ENST00000425013 / NM_207116.3; = p.E310Q on NM_207111.4) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773316583, COSV101111362; called by muse, mutect2
- RNF6 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as COSV100644662; called by muse, mutect2, varscan2
- SHISA3 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100069900; called by muse, mutect2, varscan2
- SLC4A4 | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV99141228; called by muse, mutect2, varscan2
- SPATA31A1 | c.3574dup p.T1192Nfs*14 | Frame Shift Ins (INS) | VAF 101/324 reads (31%) | catalogued as rs1405569820; called by mutect2, pindel, varscan2
- STK24 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs147189846; called by muse, mutect2, varscan2
- TBX18 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.073); catalogued as COSV100858555, COSV63738222; called by muse, mutect2, varscan2
- TDRD1 | c.3387G>C p.Q1129H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); catalogued as COSV99314964; called by muse, mutect2, varscan2
- TEDC2 | c.1219G>C p.A407P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV100709710; called by muse, mutect2, varscan2
- THSD7A | c.2183G>T p.C728F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101448664; called by muse, mutect2, varscan2
- TM7SF2 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV54204290; called by muse, mutect2, varscan2
- TMEM35A | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99515706; called by muse, mutect2, varscan2
- TMTC2 | c.1015G>C p.G339R | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV100338599, COSV100339173; called by muse, mutect2, varscan2
- TOP3B | c.1604T>G p.L535R | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64119262; called by muse, mutect2
- TRPV4 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99924943; called by muse, mutect2, varscan2
- TTN | c.33118A>G p.I11040V (on ENST00000591111; = p.I10113V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/113 reads (15%) | PolyPhen benign (0); catalogued as COSV100623901; called by muse, mutect2, varscan2
- UNC5C | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs761805868, COSV101497805; called by muse, mutect2, varscan2
- ZDBF2 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100985271; called by muse, mutect2, varscan2
- ZNF280A | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs751045225, COSV100131192, COSV57480094; called by muse, mutect2, varscan2
- ZNF404 | c.1628G>C p.R543T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV100182744; called by muse, mutect2
- ZNF827 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV101061618; called by mutect2, varscan2
- ZP3 | c.591C>G p.H197Q (on ENST00000394857 / NM_001110354.2; = p.H146Q on NM_007155.6) | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV100334646; called by muse, mutect2, varscan2
- ZSCAN29 | c.1047C>A p.H349Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV99539343; called by muse, mutect2, varscan2
- ARID2 | c.1919dup p.H641Sfs*66 | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- CAPZA1 | c.648_651del p.T217Ffs*15 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- GRIN2A | c.134_136del p.D45del | In Frame Del (DEL) | VAF 30/111 reads (27%) | called by pindel, varscan2
- HGH1 | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- MUC2 | c.564C>G p.F188L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA10 | c.2676T>C p.C892= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99289136; called by muse, mutect2
- ARSD | c.960C>A p.G320= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV99472295; called by muse, varscan2
- ART3 | c.594C>T p.L198= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1419554887, COSV100587902; called by muse, mutect2, varscan2
- BHLHE23 | c.441C>T p.A147= (on ENST00000370346; = p.A163= on NM_080606.4) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs761926645, COSV100947619; called by muse, mutect2, varscan2
- CACNG3 | c.688C>A p.R230= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV50063828, COSV99136896; called by muse, mutect2, varscan2
- CMYA5 | c.4071T>C p.S1357= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV101484268; called by muse, mutect2, varscan2
- DDX60 | c.804C>T p.C268= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV101190577; called by muse, mutect2, varscan2
- FSTL5 | c.2097C>T p.V699= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100059401; called by muse, mutect2, varscan2
- HAND1 | c.615G>A p.P205= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99163999; called by muse, mutect2, varscan2
- HBB | c.84C>T p.A28= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs748296717, COSV100092870; ClinVar: likely benign; called by muse, mutect2, varscan2
- IFT140 | c.585G>A p.L195= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV101276563; called by muse, mutect2, varscan2
- INMT | c.72C>T p.Y24= | Silent (SNP) | VAF 54/160 reads (34%) | catalogued as COSV99185115; called by muse, mutect2, varscan2
- MAP3K6 | c.804C>T p.S268= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs866898564, COSV62887344; called by muse, mutect2
- MON1A | c.1530C>T p.F510= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs775060620, COSV99616925; called by muse, mutect2, varscan2
- MROH7 | c.2454G>T p.L818= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100273835; called by muse, mutect2, varscan2
- PITPNM1 | c.2637C>T p.I879= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as rs777856464, COSV99653785; called by muse, mutect2, varscan2
- PRKAA1 | c.84T>C p.I28= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99713377; called by muse, mutect2, varscan2
- SERTAD1 | c.45G>A p.E15= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs756467050; called by muse, mutect2, varscan2
- SNRPD2 | c.333G>C p.R111= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99171317; called by muse, mutect2, varscan2
- SPTBN5 | c.2496G>A p.R832= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100311984; called by muse, mutect2, varscan2
- TRIP13 | c.819C>T p.A273= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV51319709, COSV99386500; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822985 C>G | 5'Flank (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2, varscan2
- DCHS2 | n.6566A>T | RNA (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100602346; called by muse, mutect2
- DCHS2 | n.6564C>T | RNA (SNP) | VAF 12/42 reads (29%) | catalogued as COSV61780664; called by muse, mutect2
- MARCHF1 | c.-322-85785C>G | Intron (SNP) | VAF 29/173 reads (17%) | called by muse, mutect2, varscan2
- NDUFB1 | c.-152C>A | 5'UTR (SNP) | VAF 11/76 reads (14%) | catalogued as COSV100103045; called by muse, mutect2, varscan2
- PTPRN2 | c.113-43014G>A | Intron (SNP) | VAF 12/70 reads (17%) | catalogued as rs765589180, COSV101133262; called by muse, mutect2
- SSPOP | n.5792C>T | RNA (SNP) | VAF 12/78 reads (15%) | catalogued as rs776382320, COSV50486988; called by muse, mutect2, varscan2
